Somatic mutation profile of tumor specimen 0DRE0Z from CCDI case PBCGFL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,783 days).
Specimen 0DRE0Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33f124e7-0c4e-469a-84c8-de528a0a6571.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRE0J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88bdb359-8c04-4b46-bb76-6bf941bade50

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 3, 3'UTR 2, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.676-1G>A p.X226_splice | Splice Site (SNP) | VAF 246/359 reads (69%) | catalogued as CS045486, CS982290, COSV58526489, COSV58527400; called by muse, mutect2, varscan2
- TRIP11 | c.5270G>A p.R1757Q | Missense Mutation (SNP) | VAF 126/360 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs763126312; called by muse, mutect2, varscan2
- CHAF1B | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 20/809 reads (2%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- NAA25 | c.468A>C p.L156F | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LAMB2 | c.5136G>A p.T1712= | Silent (SNP) | VAF 38/900 reads (4%) | catalogued as rs767608145; called by muse, mutect2
- PJA1 | c.1038C>T p.A346= (on ENST00000361478 / NM_145119.4; = p.A158= on NM_022368.5) | Silent (SNP) | VAF 37/1190 reads (3%) | catalogued as rs1437432245; called by muse, mutect2
- FIBCD1 | c.*33C>T | 3'UTR (SNP) | VAF 100/265 reads (38%) | catalogued as rs779340662; called by muse, mutect2, varscan2
- NONO | c.1282-25G>A | Intron (SNP) | VAF 96/327 reads (29%) | called by muse, mutect2, varscan2
- OXCT2 | c.*41_*46del | 3'UTR (DEL) | VAF 46/200 reads (23%) | called by mutect2, varscan2
- PROX2 | c.1608+46C>A | Intron (SNP) | VAF 54/165 reads (33%) | called by muse, mutect2, varscan2
- RANBP17 | c.594+19C>T | Intron (SNP) | VAF 66/221 reads (30%) | called by muse, mutect2, varscan2
